Somatic mutation profile of tumor specimen TARGET-10-PAPIHU-09A (aliquot TARGET-10-PAPIHU-09A-01D) from TARGET case TARGET-10-PAPIHU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,295 days).
Specimen TARGET-10-PAPIHU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92460902-86a1-42e2-a94d-b388733e845b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPIHU-10A (Blood Derived Normal), aliquot TARGET-10-PAPIHU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27198565-d36e-4095-998f-69e6b842e2c6

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 19/42 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- AMIGO3 | c.1288A>G p.S430G | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as rs1418565904; called by mutect2, varscan2
- FLNC | c.2513C>T p.A838V | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as rs775085661, COSV57958345, COSV57966882; called by muse, mutect2, varscan2
- JPH3 | c.1092C>A p.D364E | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.33); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- PPP1R36 | c.565G>T p.V189F | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- CPO | c.78C>A p.A26= | Silent (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2, varscan2
- DNAJB5 | c.423C>T p.F141= | Silent (SNP) | VAF 48/109 reads (44%) | catalogued as rs1275952532; called by muse, mutect2, varscan2
- FO393408.1 | n.348A>G | RNA (SNP) | VAF 11/137 reads (8%) | catalogued as rs112407074; called by muse, mutect2
- TMEM25 | c.-27-26C>T | Intron (SNP) | VAF 24/46 reads (52%) | called by muse, mutect2, varscan2
